Gene-level copy-number profile of tumor specimen ALCH-AENG-TTP1-A from ALCHEMIST case ALCH-AENG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,349 days).
Specimen ALCH-AENG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e84e5ff9-1053-44f0-9067-34b4a6fcefbb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/67a69e34-97ce-4814-91b1-d70997f22561

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 196; copy number 2: 57,832; copy number 3: 232; copy number 4: 102; copy number 5: 2; copy number 6: 25; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:92,418,667–92,420,875, 1 gene: MARK2P9.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr16:1,064,093–1,080,142, 3 genes: SSTR5-AS1, AC009041.2, SSTR5.
- chr21:41,711,520–41,717,975, 2 genes: LINC00479, LINC00112.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,219,918–70,258,930, 1 gene, copy number 5: GUSBP14.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr9:65,189,995–65,193,610, 1 gene, copy number 17: BMS1P12.
- chr12:68,842,197–69,855,363, 25 genes, copy number 6 (within-gene range 4–6): CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.

Autosomal genes at a single copy (total copy number 1): 196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
